Somatic mutation profile of tumor specimen TCGA-IB-7888-01A (aliquot TCGA-IB-7888-01A-11D-2154-08) from TCGA case TCGA-IB-7888, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 66.0 years (24,117 days).
Specimen TCGA-IB-7888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf5221dd-14d4-4d80-847c-5de9963233b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7888-10A (Blood Derived Normal), aliquot TCGA-IB-7888-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c4a392e-5037-493c-8b5f-2ac96a6bbf62

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 14/327 reads (4%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2
- ALDH1A3 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs147665432; called by muse, mutect2
- AXL | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1568413407, COSV99997239; called by muse, mutect2
- BDP1 | c.6460C>A p.L2154I | Missense Mutation (SNP) | VAF 48/605 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100703512; called by muse, mutect2
- DDO | c.521C>T p.P174L (on ENST00000368924 / NM_001368172.1; = p.P115L on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/1162 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs370285627; called by muse, mutect2
- GRIK3 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 36/586 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277838021, COSV66135068; called by muse, mutect2
- INCENP | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 40/574 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99611526; called by muse, mutect2
- KCNB1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65571493; called by muse, mutect2
- KMT2D | c.2569A>G p.K857E | Missense Mutation (SNP) | VAF 52/653 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99985675; called by muse, mutect2
- LAMP2 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 93/1521 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99568868; called by muse, mutect2
- MUC4 | c.2471C>A p.S824* | Nonsense Mutation (SNP) | VAF 47/572 reads (8%) | catalogued as COSV100642218; called by muse, mutect2
- POLK | c.2540T>C p.M847T | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1285230226, COSV99606475; called by muse, mutect2
- PTBP2 | c.808G>C p.V270L (on ENST00000426398 / NM_001300986.2; = p.V262L on NM_021190.4) | Missense Mutation (SNP) | VAF 27/509 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as COSV100930281; called by muse, mutect2
- RALGAPA2 | c.4692T>G p.I1564M | Missense Mutation (SNP) | VAF 22/391 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99174986; called by muse, mutect2
- SLC1A3 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 70/896 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs750317354, COSV54318200; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A19 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 62/846 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs200783817; called by muse, mutect2
- TGM7 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.978); catalogued as COSV101476898; called by muse, mutect2
- ZNF480 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 25/399 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs1350576028, COSV100574310; called by muse, mutect2
- ZNF70 | c.761G>C p.C254S | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558955; called by muse, mutect2
- ZC2HC1A | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- ASB15 | c.1560A>G p.V520= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as COSV99306463; called by muse, mutect2
- CFAP58 | c.2301C>T p.R767= | Silent (SNP) | VAF 30/349 reads (9%) | catalogued as COSV100866174; called by muse, mutect2
- CHST1 | c.1122C>T p.N374= | Silent (SNP) | VAF 20/542 reads (4%) | catalogued as rs1299303782, COSV57323984; called by muse, mutect2
- CILP2 | c.1851G>A p.S617= | Silent (SNP) | VAF 48/794 reads (6%) | catalogued as COSV99365168; called by muse, mutect2
- DOCK8 | c.987G>A p.A329= | Silent (SNP) | VAF 27/300 reads (9%) | catalogued as rs1013880203, COSV101210326; ClinVar: likely benign; called by muse, mutect2
- PTK2B | c.753C>T p.F251= | Silent (SNP) | VAF 29/572 reads (5%) | catalogued as COSV57750559; called by muse, mutect2
- ZBTB3 | c.1533G>A p.G511= | Silent (SNP) | VAF 23/428 reads (5%) | catalogued as COSV101189006; called by muse, mutect2
